TCGA case TCGA-IZ-A6M8 — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: ABS - Lahey Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/886ce4a0-a78d-4976-9667-041385c9b6d5

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Alive.

Diagnoses (3)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 69.9 years (25,545 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC clinical T: T1a; AJCC clinical N: N0; AJCC clinical M: MX; AJCC clinical stage: Stage I; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 497 days (1.4 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the prostate gland (histology not recorded by GDC). Age at diagnosis: 57.6 years (21,046 days); Days to diagnosis: -4,499 days (-12.3 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -4,440 days (-12.2 years); Treatment anatomic sites: Prostate.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Papillary squamous cell carcinoma: ICD-O-3 morphology code: 8052/3; Tissue or organ of origin: Kidney, NOS; Laterality: Left; Classification of tumor: Synchronous primary; Age at diagnosis: 69.9 years (25,545 days).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 132 days; Treatment anatomic sites: Kidney.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 146 days; Disease response: Tumor Free.
- Days to follow up: 497 days (1.4 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 106.6 kg; Height: 189 cm; BMI: 29.8.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Pack years smoked: 15.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IZ-A6M8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-IZ-A6M8-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 90; Percent neutrophil infiltration: 0.
- Sample TCGA-IZ-A6M8-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IZ-A6M8-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: No; Tobacco smoking history indicator: 5; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free.
- Other malignancy form 1: Malignancy type: Synchronous Malignancy; Other malignancy histological type: Papillary Squamous Cell.
- Other malignancy form 1, Surgery: Other malignancy surgery type: laparoscopic radical nephrectomy.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate.
- Other malignancy form 2, Surgery: Other malignancy surgery type: radical retropubic prostatectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 497 days; disease-specific survival: no event (censored), 497 days; disease-free interval: no event (censored), 497 days; progression-free interval: no event (censored), 497 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IZ-A6M8-01A-11D-A31W-01): tumor purity 0.64, ploidy 2.12, whole-genome doublings 0.
